CCDI case PBCEZL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a4aa8b2b-bb6a-4e6f-9692-2358d066276a

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,780 days).

Biospecimens (3 samples)
- Sample 0DQMPQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQMQ4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQMQV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
